Somatic mutation profile of tumor specimen C3N-02295-04 (aliquot CPT0187550007) from CPTAC case C3N-02295, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 56.3 years (20,557 days).
Specimen C3N-02295-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c17d0e8-53fd-40a2-9df3-66cc47ee91e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02295-31 (Blood Derived Normal), aliquot CPT0187580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddb2d3bc-9443-4e1d-b8e1-e44b887c933d

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 4, Silent 1, Nonsense Mutation 1, RNA 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60092247; called by muse, mutect2
- CHST3 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1379390092; called by muse, mutect2
- DNMT1 | c.4145C>T p.S1382L | Missense Mutation (SNP) | VAF 40/689 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs375225009; ClinVar: uncertain significance; called by muse, mutect2
- ELOA2 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 69/1210 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs746916831, COSV55294102; called by muse, mutect2
- GPR78 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 27/662 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs992535486; called by muse, mutect2
- HECW1 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 20/584 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.052); catalogued as rs1298572393; called by muse, mutect2
- IGSF9 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 37/395 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185127478, COSV63642381; called by muse, mutect2
- NCOR1 | c.5453C>T p.A1818V | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs762213757, COSV51995559; called by muse, mutect2
- NRK | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 30/335 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1485051577; called by muse, mutect2
- OR56A1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 34/691 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs150942884; called by muse, mutect2
- RYR2 | c.13630G>A p.V4544M | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as rs1235379196; called by muse, mutect2
- SCAF1 | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs140638428; called by muse, mutect2
- TENM4 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 28/691 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as rs901986243; called by muse, mutect2
- TMEM132C | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1029079183, COSV59418366; called by muse, mutect2
- ZBTB8B | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1351303428; called by muse, mutect2
- ZNF831 | c.4886C>T p.P1629L | Missense Mutation (SNP) | VAF 26/600 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV64043405; called by muse, mutect2
- BLK | c.1469T>A p.L490Q | Missense Mutation (SNP) | VAF 42/1113 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOP1B | c.1888A>G p.I630V | Missense Mutation (SNP) | VAF 30/778 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2
- EFR3B | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 32/596 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.12); called by muse, mutect2
- FHL2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 62/1179 reads (5%) | called by muse, mutect2
- KLC2 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); called by muse, mutect2
- PKD1L3 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- TNR | c.673T>G p.Y225D | Missense Mutation (SNP) | VAF 44/466 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- DMRTB1 | c.474G>A p.A158= | Silent (SNP) | VAF 31/500 reads (6%) | called by muse, mutect2
- DMAP1 | c.198-108G>C | Intron (SNP) | VAF 13/344 reads (4%) | called by muse, mutect2
- FAM183BP | n.1020C>T | RNA (SNP) | VAF 82/850 reads (10%) | catalogued as rs749219684; called by muse, mutect2
- MAGI2 | c.3706+9C>T | Intron (SNP) | VAF 30/304 reads (10%) | called by muse, mutect2, varscan2
- PAX9 | c.632-46G>A | Intron (SNP) | VAF 12/132 reads (9%) | catalogued as rs371819672, COSV64061491; called by muse, mutect2
- RNA5-8SP2 | chr16:34159700 G>A | 5'Flank (SNP) | VAF 24/496 reads (5%) | called by muse, mutect2
- SLC25A45 | c.37+41G>A | Intron (SNP) | VAF 17/394 reads (4%) | called by muse, mutect2
- SLC7A5 | c.*26G>T | 3'UTR (SNP) | VAF 21/502 reads (4%) | called by muse, mutect2
